Gene-level copy-number profile of tumor specimen ALCH-B280-TTP1-A from ALCHEMIST case ALCH-B280, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 71.5 years (26,103 days).
Specimen ALCH-B280-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 66a820d0-c734-4d76-9829-9b2ef93bd1ad.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B280-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,222 have no estimate.
https://portal.gdc.cancer.gov/files/09144e91-c920-46e4-8a2e-ec85b09de06a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 61; copy number 1: 1,231; copy number 2: 55,458; copy number 3: 1,356; copy number 4: 96; copy number 5: 41; copy number 6: 46; copy number 7: 69; copy number 8: 27; copy number 14: 16.

Homozygous deletions (total copy number 0; autosomes only): 61 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:43,542,076–46,028,892, 4 genes: AC134698.2, AC139365.2, AC139365.1, AC118650.1.
- chr13:112,313,467–112,331,225, 2 genes: LINC01043, LINC01044.
- chr14:73,237,497–73,274,640, 4 genes (within-gene range 0–2): PAPLN, AC004846.1, RNU6-419P, AC004846.2.
- chr15:25,169,337–25,257,027, 46 genes (within-gene range 0–2): DMAC1P1, SNORD115-1, SNORD115-2, SNORD115-3, SNORD115-4, SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30, SNORD115-31, SNORD115-32, SNORD115-33, SNORD115-34, SNORD115-35, SNORD115-36, SNORD115-37, SNORD115-38, SNORD115-39, SNORD115-40, SNORD115-41, SNORD115-42, SNORD115-43, SNORD115-44, AC124303.1.
- chr15:77,568,970–77,608,888, 1 gene: AC046168.2.
- chr17:79,074,824–79,088,599, 1 gene: ENGASE.
- chr20:61,717,506–61,755,056, 2 genes (within-gene range 0–2): AL162457.1, AL162457.2.
- chr21:43,322,417–43,332,039, 1 gene: LINC00322.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 199 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:58,715,609–58,784,048, 2 genes, copy number 5: AL136985.3, JUN.
- chr12:57,546,026–58,813,060, 43 genes, copy number 6 (within-gene range 2–6): KIF5A, PIP4K2C, DTX3, ARHGEF25, AC025165.1, AC025165.6, SLC26A10, B4GALNT1, RPL13AP23, OS9, AC025165.2, AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2, AC083805.1, AC083805.3, ATP23, GIHCG, AC084033.1, RN7SKP65, AC084033.2, LINC02403, AC090643.1, AC090643.2, RPL21P103, AC025578.1, AC020637.1, LINC02388.
- chr12:62,466,817–62,935,802, 12 genes, copy number 5: MON2, AC079035.1, RNU6-399P, LINC01465, AC048341.1, MIRLET7I, AC048341.2, PPM1H, RPL32P26, GAPDHP44, RNU1-83P, Y_RNA.
- chr12:63,623,788–63,795,718, 2 genes, copy number 6 (within-gene range 2–7): AC084357.2, AC027667.1.
- chr12:63,760,358–64,881,033, 38 genes, copy number 6–7: AC084357.1, RXYLT1, RXYLT1-AS1, PABPC1P4, SRGAP1, RPL36AP41, AC079866.2, AC079866.1, AC020611.1, AC020611.2, AC025576.3, AC025576.2, AC025576.1, C12orf66, RNU6-1009P, AC012158.1, RNU5A-7P, C12orf56, OOEPP2, ATP6V1E1P3, AC135279.1, XPOT, AC135279.2, AC135279.3, TBK1, AC136977.1, RASSF3, AC078962.2, SNORD83, AC078962.4, MIR548C, MIR548Z, AC078962.1, AC078962.3, AC025262.2, AC025262.1, GNS, TBC1D30.
- chr12:64,820,179–64,868,699, 2 genes, copy number 7: AC025262.3, RPL7P39.
- chr12:66,023,620–70,637,440, 100 genes, copy number 5–14 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,231. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
